Somatic mutation profile of tumor specimen TCGA-42-2588-01A (aliquot TCGA-42-2588-01A-01D-1526-09) from TCGA case TCGA-42-2588, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 61.3 years (22,377 days).
Specimen TCGA-42-2588-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfbdf179-9e1a-4356-add3-9b3b7b040abd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-42-2588-10A (Blood Derived Normal), aliquot TCGA-42-2588-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55d8f676-56d5-4740-bf7e-44eb38fcae96

The open-access MAF lists 40 somatic variants for this specimen: 30 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 26, Silent 10, Frame Shift Del 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKZF1 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs771781981, COSV55478469; called by muse, mutect2, varscan2
- ATP12A | c.1985G>A p.R662H | Missense Mutation (SNP) | VAF 139/467 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs370861260; called by muse, mutect2, varscan2
- CCDC62 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 86/345 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53432234; called by muse, mutect2, varscan2
- CDK12 | c.833dup p.Y279Lfs*19 | Frame Shift Ins (INS) | VAF 226/396 reads (57%) | catalogued as COSV101420218; called by mutect2, pindel, varscan2
- CFAP46 | c.7649G>A p.R2550Q | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.261); catalogued as rs375166106; called by muse, mutect2, varscan2
- CKAP5 | c.4309G>A p.E1437K | Missense Mutation (SNP) | VAF 67/614 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.473); catalogued as COSV56373081; called by muse, mutect2, varscan2
- CLPX | c.292A>G p.K98E | Missense Mutation (SNP) | VAF 77/282 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV55646206; called by muse, mutect2, varscan2
- DDX50 | c.1177A>G p.I393V | Missense Mutation (SNP) | VAF 33/409 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as rs1258786115, COSV101007157; called by muse, mutect2
- FAM120C | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV60261971; called by muse, mutect2, varscan2
- GUCY2F | c.2021G>A p.R674Q | Missense Mutation (SNP) | VAF 68/304 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as rs765768638, COSV54307314; called by muse, mutect2, varscan2
- HHIPL2 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 76/243 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs147794680; called by muse, mutect2, varscan2
- KIAA0319 | c.1826C>A p.S609Y | Missense Mutation (SNP) | VAF 138/822 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV65501612; called by muse, mutect2, varscan2
- LHX3 | c.850G>C p.G284R (on ENST00000371748 / NM_178138.6; = p.G289R on NM_014564.5) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as COSV65583110; called by muse, mutect2, varscan2
- LPCAT2 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 76/442 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs141449615; called by muse, mutect2, varscan2
- MYH2 | c.3542G>A p.R1181H | Missense Mutation (SNP) | VAF 122/202 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs773196254, COSV55446689; called by muse, mutect2, varscan2
- MYOC | c.842C>A p.T281N | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV50677785; called by muse, mutect2, varscan2
- NOL4L | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 142/531 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.242); catalogued as rs371649171, COSV62890143; called by muse, mutect2, varscan2
- PHF12 | c.119G>A p.S40N | Missense Mutation (SNP) | VAF 87/223 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.533); catalogued as rs1308708452, COSV52021703; called by muse, mutect2, varscan2
- PKD2L1 | c.806G>A p.G269D | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58398341; called by muse, mutect2, varscan2
- SIPA1L1 | c.4986G>A p.M1662I | Missense Mutation (SNP) | VAF 85/324 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.841); catalogued as rs772380479, COSV62173032; called by muse, mutect2, varscan2
- SLIT2 | c.2681A>G p.D894G | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV56591163; called by muse, mutect2, varscan2
- TBX3 | c.1175C>T p.A392V (on ENST00000257566 / NM_016569.4; = p.A372V on NM_005996.4) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.066); catalogued as rs1214834962, COSV57470971; called by muse, mutect2, varscan2
- TFAP2B | c.1376G>A p.R459K | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs765707474, COSV53830670; called by muse, mutect2, varscan2
- TP53 | c.1014del p.F338Lfs*7 | Frame Shift Del (DEL) | VAF 53/115 reads (46%) | catalogued as COSV52857417, COSV52875604, COSV52988223; called by mutect2, pindel, varscan2
- TPTE | c.1286G>A p.R429H (on ENST00000618007 / NM_199261.4; = p.R411H on NM_199259.4) | Missense Mutation (SNP) | VAF 62/813 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as rs746164402; called by muse, mutect2
- TTLL6 | c.2153C>T p.T718M (on ENST00000393382 / NM_001130918.3; = p.T411M on NM_173623.3) | Missense Mutation (SNP) | VAF 115/189 reads (61%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs761943581, COSV64976589; called by muse, mutect2, varscan2
- ZFP69 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV65529494; called by muse, mutect2, varscan2
- ZNF622 | c.635A>G p.D212G | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as rs953136844, COSV58075017; called by muse, mutect2, varscan2
- CIITA | c.1019_1023del p.Q340Lfs*58 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | called by mutect2, pindel, varscan2
- IQSEC1 | c.2535del p.N846Tfs*27 | Frame Shift Del (DEL) | VAF 242/667 reads (36%) | called by mutect2, pindel, varscan2
- EMC10 | c.447C>T p.H149= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs760587429, COSV100618375; called by muse, mutect2
- LILRA6 | c.1173G>T p.A391= | Silent (SNP) | VAF 107/534 reads (20%) | called by muse, mutect2, varscan2
- LRRC73 | c.84C>T p.N28= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV52503332; called by muse, mutect2, varscan2
- MPC2 | c.279T>C p.N93= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs537213051, COSV54797447, COSV54797519; called by muse, mutect2, varscan2
- NEBL | c.138G>A p.T46= | Silent (SNP) | VAF 106/571 reads (19%) | catalogued as rs752942716, COSV65799480, COSV65799571; called by muse, mutect2, varscan2
- NPHS1 | c.3336C>T p.N1112= | Silent (SNP) | VAF 37/122 reads (30%) | catalogued as rs1053234526, COSV62289633; called by muse, mutect2, varscan2
- PARP16 | c.405C>T p.N135= | Silent (SNP) | VAF 64/366 reads (17%) | catalogued as rs891750608, COSV56036083; called by muse, mutect2, varscan2
- PCDHA5 | c.1554G>A p.A518= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as COSV65354769; called by muse, mutect2, varscan2
- PCDHGA11 | c.246C>T p.S82= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs907282414, COSV53921097; called by muse, mutect2
- SBNO1 | c.618C>T p.N206= (on ENST00000420886; = p.N205= on NM_018183.5) | Silent (SNP) | VAF 138/484 reads (29%) | catalogued as rs780595017, COSV57338794; called by muse, mutect2
